Gene-level copy-number profile of tumor specimen ALCH-B27T-TTP1-A from ALCHEMIST case ALCH-B27T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.9 years (15,653 days).
Specimen ALCH-B27T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 341ed4d6-0ba5-4207-8855-0951b510dcd5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/9e82f969-11ea-4d8c-83f7-8e2e76208851

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 125; copy number 1: 9,040; copy number 2: 49,052; copy number 3: 647; copy number 4: 15; copy number 5: 4; copy number 7: 3; copy number 8: 2; copy number 9: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene: AC114498.1.
- chr1:179,816,184–179,818,191, 1 gene (within-gene range 0–1): AL359853.1.
- chr1:180,154,869–180,278,984, 2 genes (within-gene range 0–2): QSOX1, LHX4.
- chr1:212,950,520–212,992,037, 1 gene: VASH2.
- chr1:235,547,685–235,650,754, 3 genes (within-gene range 0–2): GNG4, FO393422.1, AL583844.1.
- chr2:89,906,757–89,916,052, 2 genes: IGKV3D-34, IGKV1D-33.
- chr2:109,313,571–109,313,625, 1 gene (within-gene range 0–2): MIR4266.
- chr3:49,857,988–49,877,305, 3 genes: CAMKV, RN7SL217P, ACTBP13.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:1,712,891–1,745,171, 2 genes (within-gene range 0–2): TACC3, TMEM129.
- chr4:49,523,648–49,523,857, 1 gene: AC119751.2.
- chr7:5,306,790–5,513,809, 9 genes (within-gene range 0–2): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr7:23,490,473–23,491,893, 2 genes: RPS2P32, Y_RNA.
- chr7:151,028,422–151,057,897, 4 genes (within-gene range 0–2): ABCB8, AC010973.1, ASIC3, CDK5.
- chr11:77,128,246–77,215,241, 1 gene: MYO7A.
- chr12:124,529,722–124,530,228, 1 gene (within-gene range 0–1): AC073592.7.
- chr14:23,412,740–23,435,660, 3 genes (within-gene range 0–2): MYH7, AL132855.1, MIR208B.
- chr14:34,568,689–34,569,129, 1 gene (within-gene range 0–2): RPS19P3.
- chr14:96,592,399–96,605,974, 1 gene: AL137786.1.
- chr15:101,495,052–101,495,567, 1 gene (within-gene range 0–2): AC090164.2.
- chr16:4,532,216–4,533,670, 1 gene (within-gene range 0–2): AC023830.3.
- chr17:3,896,592–3,964,464, 2 genes: P2RX1, ATP2A3.
- chr17:10,792,059–10,838,094, 5 genes (within-gene range 0–2): AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT.
- chr17:18,225,635–18,244,875, 1 gene (within-gene range 0–1): LLGL1.
- chr17:20,633,034–20,633,259, 1 gene (within-gene range 0–2): AC087499.7.
- chr17:45,999,250–45,999,694, 1 gene (within-gene range 0–2): STH.
- chr17:67,774,591–67,785,293, 2 genes: RPSAP67, RPL17P41.
- chr19:17,207,138–17,255,448, 5 genes (within-gene range 0–2): AC020913.2, USE1, OCEL1, NR2F6, AC010646.1.
- chr19:19,645,198–19,663,676, 1 gene: ATP13A1.
- chr19:33,207,129–33,225,850, 3 genes (within-gene range 0–2): AC008738.7, SLC7A10, AC008738.4.
- chr20:62,774,121–62,776,996, 1 gene: LINC00659.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,789,376, 1 gene, copy number 7: NCF1.
- chr7:74,894,116–74,913,310, 3 genes, copy number 5–8: PMS2P5, Y_RNA, SPDYE12P.
- chr9:136,107,808–136,118,875, 2 genes, copy number 5: LINC02846, TMEM250.
- chr10:87,751,512–87,841,343, 1 gene, copy number 5 (within-gene range 2–5): ATAD1.
- chr11:63,759,892–63,768,775, 1 gene, copy number 7: C11orf95.
- chr14:105,639,559–105,644,790, 1 gene, copy number 7 (within-gene range 2–7): IGHG2.
- chr21:43,446,601–43,479,534, 3 genes, copy number 9–26: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
